Somatic mutation profile of tumor specimen SM-JU34I (aliquot 7316UP-2058) from CPTAC case C827913, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Temporal lobe; Tumor grade: G4.
Specimen SM-JU34I: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d6c20006-3cbc-4e62-be28-be51b27af870.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 1105217 (Blood Derived Normal), aliquot 7316UP-2058-1105217; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/622ef294-bd51-4394-b039-54f5d9f23c62

The open-access MAF lists 35 somatic variants for this specimen: 25 protein-altering or splice-affecting, 6 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Silent 6, Intron 3, Nonsense Mutation 2, In Frame Del 2, Splice Site 1, 5'Flank 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTPN11 | c.1517A>C p.Q506P | Missense Mutation (SNP) | VAF 140/429 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.784); catalogued as rs397507548, CM031338, COSV61007665; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA2 | c.7063C>A p.H2355N (on ENST00000614293; = p.H2325N on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 134/399 reads (34%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs767037178; called by muse, mutect2, varscan2
- CARD11 | c.139C>T p.R47C | Missense Mutation (SNP) | VAF 119/338 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62718328; called by muse, mutect2, varscan2
- CFAP157 | c.1495C>T p.R499C | Missense Mutation (SNP) | VAF 52/148 reads (35%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.533); catalogued as rs752171285, COSV58852665, COSV58853238; called by muse, mutect2, varscan2
- CYP4B1 | c.821G>A p.R274Q | Missense Mutation (SNP) | VAF 67/214 reads (31%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as rs45578838; called by muse, mutect2, varscan2
- DDX19B | c.389C>T p.P130L | Missense Mutation (SNP) | VAF 54/168 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs933326553, COSV99850261; called by muse, mutect2, varscan2
- DDX3X | c.821C>T p.T274M (on ENST00000399959; = p.T275M on NM_001356.5) | Missense Mutation (SNP) | VAF 41/58 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67863061; called by muse, mutect2, varscan2
- FGF7 | c.536del p.T179Rfs*15 | Frame Shift Del (DEL) | VAF 14/72 reads (19%) | catalogued as COSV51067637; called by mutect2, pindel
- MSH4 | c.1048C>T p.R350* | Nonsense Mutation (SNP) | VAF 53/213 reads (25%) | catalogued as rs146479652; called by muse, mutect2, varscan2
- MUSK | c.2155C>T p.R719C | Missense Mutation (SNP) | VAF 114/340 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs769211968, COSV51895728; called by muse, mutect2, varscan2
- PDLIM2 | c.910C>T p.R304W (on ENST00000397760; = p.R554W on NM_021630.6) | Missense Mutation (SNP) | VAF 41/102 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs147368012; called by muse, mutect2, varscan2
- TNNI1 | c.329G>A p.R110H | Missense Mutation (SNP) | VAF 56/177 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs771001056, COSV60188941; called by muse, mutect2, varscan2
- AP1M1 | c.178A>T p.I60F | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.236); called by muse, mutect2, varscan2
- CENPB | c.435C>G p.N145K | Missense Mutation (SNP) | VAF 65/154 reads (42%) | SIFT tolerated (0.36); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- HCN1 | c.2057A>T p.Q686L | Missense Mutation (SNP) | VAF 88/240 reads (37%) | SIFT tolerated, low confidence (0.43); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- IL12RB2 | c.1559-1G>A p.X520_splice | Splice Site (SNP) | VAF 179/532 reads (34%) | called by muse, mutect2, varscan2
- LILRB2 | c.1096C>A p.L366I | Missense Mutation (SNP) | VAF 166/498 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.697); called by muse, mutect2, varscan2
- NF1 | c.5361_5363del p.E1787_I1788delinsD (on ENST00000358273 / NM_001042492.3; = p.E1766_I1767delinsD on NM_000267.3) | In Frame Del (DEL) | VAF 130/239 reads (54%) | called by mutect2, pindel, varscan2
- PGK2 | c.856T>A p.F286I | Missense Mutation (SNP) | VAF 81/197 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.573); called by muse, mutect2, varscan2
- PIK3R1 | c.1695_1703del p.S565_P568delinsR (on ENST00000521381 / NM_181523.3; = p.S295_P298delinsR on NM_181504.4) | In Frame Del (DEL) | VAF 50/146 reads (34%) | called by mutect2, pindel, varscan2
- PRDM15 | c.3409A>C p.N1137H | Missense Mutation (SNP) | VAF 49/171 reads (29%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- RPL5 | c.284dup p.Y95* | Nonsense Mutation (INS) | VAF 102/328 reads (31%) | called by mutect2, pindel, varscan2
- SMCP | c.253A>G p.M85V | Missense Mutation (SNP) | VAF 110/348 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TTN | c.3614C>A p.T1205K (on ENST00000591111; = p.T1159K on NM_003319.4) | Missense Mutation (SNP) | VAF 104/458 reads (23%) | PolyPhen benign (0.019); called by muse, mutect2
- U2SURP | c.1105A>G p.M369V | Missense Mutation (SNP) | VAF 63/192 reads (33%) | SIFT tolerated (0.25); PolyPhen benign (0.011); called by muse, varscan2
- HTR5A | c.588C>T p.R196= | Silent (SNP) | VAF 145/385 reads (38%) | catalogued as COSV55282570; called by muse, mutect2, varscan2
- LTK | c.975C>A p.G325= | Silent (SNP) | VAF 38/76 reads (50%) | catalogued as rs1284727107; called by muse, mutect2, varscan2
- MARCHF11 | c.309G>A p.G103= | Silent (SNP) | VAF 27/71 reads (38%) | called by muse, mutect2, varscan2
- NAA20 | c.24C>T p.T8= | Silent (SNP) | VAF 122/328 reads (37%) | catalogued as rs1261543479, COSV100131621; called by muse, mutect2, varscan2
- PZP | c.234G>A p.A78= | Silent (SNP) | VAF 71/188 reads (38%) | catalogued as rs368446783, COSV54353837; called by muse, mutect2, varscan2
- TTN | c.57612G>A p.T19204= (on ENST00000591111; = p.T11780= on NM_003319.4) | Silent (SNP) | VAF 133/467 reads (28%) | catalogued as rs377275061; called by muse, mutect2, varscan2
- CASP8 | c.802+50T>G | Intron (SNP) | VAF 47/119 reads (39%) | called by muse, mutect2, varscan2
- RBFOX1 | c.996-15731G>A | Intron (SNP) | VAF 39/135 reads (29%) | catalogued as rs900149341, COSV60967333, COSV60976172; called by muse, mutect2, varscan2
- RFK | chr9:76398753 C>T | 5'Flank (SNP) | VAF 86/279 reads (31%) | called by muse, mutect2, varscan2
- TMEM107 | c.87+86C>G | Intron (SNP) | VAF 54/153 reads (35%) | called by muse, mutect2, varscan2
